Somatic mutation profile of tumor specimen TCGA-12-0619-01A (aliquot TCGA-12-0619-01A-01D-1492-08) from TCGA case TCGA-12-0619, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.0 years (21,920 days).
Specimen TCGA-12-0619-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78e2ebfe-df9e-41f4-9daf-c9a60a14711b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0619-10A (Blood Derived Normal), aliquot TCGA-12-0619-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd9988c2-3c4a-4601-89c8-2f4202663841

The open-access MAF lists 56 somatic variants for this specimen: 46 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 39, Silent 10, Nonsense Mutation 3, Frame Shift Ins 2, Nonstop Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A1 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 151/417 reads (36%) | catalogued as rs72667036, CD137833, CM980389, COSV56808037; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 607/4341 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853294, CD135177, CM920603, COSV57295487; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.490A>G p.K164E | Missense Mutation (SNP) | VAF 46/65 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs879254249, COSV52676020, COSV52700231, COSV52728094, COSV52766542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA6 | c.2874G>T p.K958N | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV52644420; called by muse, mutect2, varscan2
- ADGRF5 | c.322A>G p.T108A | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV51939678; called by muse, mutect2, varscan2
- ARIH1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV65912923; called by muse, mutect2, varscan2
- CD99L2 | c.380A>G p.D127G | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV60938359; called by muse, mutect2, varscan2
- CELF4 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs372830155; called by muse, mutect2, varscan2
- COLGALT1 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53111441; called by muse, mutect2, varscan2
- CYP4B1 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs779184367, COSV54725220; called by muse, mutect2, varscan2
- DNAH5 | c.10796G>C p.R3599P | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54207393, COSV54249998; called by muse, mutect2, varscan2
- DROSHA | c.2332C>T p.R778C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as rs1458058411, COSV60772747; called by muse, mutect2, varscan2
- EAPP | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 41/112 reads (37%) | catalogued as rs754374098, COSV51653161; called by muse, mutect2, varscan2
- GNB4 | c.201dup p.R68Qfs*17 | Frame Shift Ins (INS) | VAF 91/278 reads (33%) | catalogued as rs35612039; called by mutect2, pindel, varscan2
- GPR32 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV54514727; called by muse, mutect2, varscan2
- GRAMD2B | c.1036A>T p.I346F | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV53506728, COSV53509950; called by muse, mutect2, varscan2
- HTR1E | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 105/254 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as rs749518023, COSV100541258, COSV59507135; called by muse, mutect2, varscan2
- IGSF22 | c.2491C>T p.P831S (on ENST00000319338; = p.P932S on NM_173588.4) | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.651); catalogued as rs1229128953, COSV55011860; called by muse, mutect2, varscan2
- KLHL4 | c.1393C>A p.R465S | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV64140630, COSV64147567; called by muse, mutect2, varscan2
- KRT12 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV52430300; called by muse, mutect2, varscan2
- LONP2 | c.1055G>A p.R352K | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1363843539, COSV53525969; called by muse, mutect2
- LYST | c.10429A>G p.S3477G | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.661); catalogued as COSV67713616; called by muse, mutect2, varscan2
- MAGEC2 | c.33C>A p.N11K | Missense Mutation (SNP) | VAF 178/218 reads (82%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.079); catalogued as COSV55998658, COSV55999826; called by muse, mutect2, varscan2
- MAP3K1 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68123876; called by muse, mutect2, varscan2
- OR10A3 | c.944G>T p.*315Lext*3 | Nonstop Mutation (SNP) | VAF 32/66 reads (48%) | catalogued as COSV62460449; called by muse, varscan2
- PAX4 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs765561668, COSV58387623; called by muse, mutect2, varscan2
- PCDHB2 | c.1501C>A p.P501T | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as COSV50629426, COSV50634172; called by muse, mutect2, varscan2
- PLXNA4 | c.2890G>A p.G964R | Missense Mutation (SNP) | VAF 157/742 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58120954; called by muse, mutect2, varscan2
- PMFBP1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs751072461, COSV52831371; called by muse, mutect2, varscan2
- PPP1R26 | c.3524G>C p.R1175T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.077); catalogued as COSV63357278; called by muse, mutect2, varscan2
- PTPN12 | c.1942A>G p.M648V | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs774718567, COSV50362085; called by muse, mutect2, varscan2
- PTPRU | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775138343, COSV60536048; called by muse, mutect2, varscan2
- RYR2 | c.10810C>T p.R3604W | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1270634022, COSV63688955; called by muse, mutect2, varscan2
- SBK2 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as rs765741979, COSV60015893; called by mutect2, varscan2
- SDK1 | c.4039G>A p.V1347M | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs898481545, COSV67387560; called by muse, mutect2, varscan2
- SEZ6L2 | c.1246G>A p.V416M (on ENST00000308713 / NM_001114099.3; = p.V346M on NM_012410.4) | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs775884420, COSV58100305; called by muse, mutect2, varscan2
- SHANK1 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53261308; called by muse, mutect2, varscan2
- SKAP2 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866446687, COSV61727022; called by muse, mutect2, varscan2
- SLC2A14 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as rs1164863969, COSV100533861, COSV61588486; called by muse, mutect2, varscan2
- SYNE3 | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); catalogued as rs141951711; called by muse, mutect2, varscan2
- TBC1D9 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as rs752645201, COSV104437118, COSV71308742; called by muse, mutect2
- TMEM236 | c.410C>A p.S137Y | Missense Mutation (SNP) | VAF 307/471 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV57738836; called by muse, mutect2, varscan2
- TTYH1 | c.1348_1351del p.I450Efs*26 | Frame Shift Del (DEL) | VAF 106/270 reads (39%) | catalogued as rs768973830; called by mutect2, pindel, varscan2
- ZPBP | c.410T>C p.I137T | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV50433393; called by muse, mutect2, varscan2
- SCN11A | c.3567dup p.L1190Afs*20 | Frame Shift Ins (INS) | VAF 16/74 reads (22%) | called by mutect2, pindel, varscan2
- ACSM2A | c.1428G>A p.S476= (on ENST00000219054; = p.S397= on NM_001308169.2) | Silent (SNP) | VAF 45/142 reads (32%) | catalogued as rs773909818, COSV54585683; called by muse, mutect2, varscan2
- ADA | c.381C>T p.D127= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs7344760, COSV100866642; called by muse, varscan2
- ETV5 | c.39C>T p.V13= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV60506303; called by muse, mutect2, varscan2
- GRIA2 | c.2634C>T p.I878= | Silent (SNP) | VAF 78/312 reads (25%) | catalogued as COSV52383121; called by muse, mutect2, varscan2
- HCK | c.714G>A p.S238= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs147876395; called by muse, mutect2, varscan2
- HS3ST4 | c.1221G>A p.R407= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV58829727; called by muse, mutect2, varscan2
- ODF2 | c.501C>T p.H167= (on ENST00000434106 / NM_153433.2; = p.H143= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 23/242 reads (10%) | catalogued as rs1319957124, COSV63548846; called by muse, mutect2
- PCDHA10 | c.1359G>A p.A453= | Silent (SNP) | VAF 74/187 reads (40%) | catalogued as rs372428918, COSV56494213; called by muse, mutect2, varscan2
- RSPH6A | c.108G>A p.L36= | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as COSV55575204; called by muse, mutect2, varscan2
- SCN10A | c.3759C>T p.R1253= | Silent (SNP) | VAF 65/208 reads (31%) | catalogued as rs749134108, COSV71860180; ClinVar: likely benign; called by muse, mutect2, varscan2
